Somatic mutation profile of tumor specimen 0DGJ84 from CCDI case PBBTKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (296 days).
Specimen 0DGJ84: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7529a82-6169-4c44-bb4c-74c2664b5aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGJ63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57bdb62e-60e5-47db-a088-aab1f93afdc4

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD2 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 26/531 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs1202061917; called by muse, mutect2
- CPSF6 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs1454644338; called by muse, mutect2, varscan2
- FLT4 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 34/732 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV99987701; called by muse, mutect2
- KCNN2 | c.719G>A p.R240Q (on ENST00000264773; = p.R452Q on NM_021614.4) | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs1453730945, COSV53284095; called by muse, mutect2, varscan2
- SMYD1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 112/470 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs747099457, COSV70224809; called by muse, mutect2
- ZFP92 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 117/384 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs782078762; called by muse, mutect2, varscan2
- APCDD1L | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- LPAR4 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 38/575 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- PCLO | c.4753A>T p.I1585F | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.316); called by muse, mutect2
- SLC6A8 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- TMEM222 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDF | c.384C>A p.P128= | Silent (SNP) | VAF 29/428 reads (7%) | called by muse, mutect2
- PXDNL | c.2091G>A p.P697= | Silent (SNP) | VAF 11/366 reads (3%) | catalogued as COSV62487076, COSV62491600; called by muse, mutect2
- FGF3 | c.*97C>T | 3'UTR (SNP) | VAF 44/124 reads (35%) | catalogued as rs941457067; called by muse, mutect2, varscan2
